Somatic mutation profile of tumor specimen TCGA-A4-A57E-01A (aliquot TCGA-A4-A57E-01A-11D-A26P-10) from TCGA case TCGA-A4-A57E, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 59.9 years (21,885 days).
Specimen TCGA-A4-A57E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 933a8cc7-2024-4cc8-a5a9-e1c1d32e4128.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A57E-10A (Blood Derived Normal), aliquot TCGA-A4-A57E-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fb4f90c-2f61-421a-a7fb-df5729a98d56

The open-access MAF lists 87 somatic variants for this specimen: 64 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Frame Shift Del 4, Intron 4, Nonsense Mutation 3, Frame Shift Ins 3, 3'UTR 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 66/89 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.801G>T p.M267I | Missense Mutation (SNP) | VAF 119/213 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV56643576; called by muse, mutect2, varscan2
- ABT1 | c.118A>T p.K40* | Nonsense Mutation (SNP) | VAF 67/169 reads (40%) | catalogued as COSV51291373; called by muse, mutect2, varscan2
- ADAMTS2 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs1395544949, COSV52374775; called by muse, mutect2, varscan2
- ADAMTS3 | c.3476G>A p.S1159N | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs747438401, COSV54391249; called by muse, mutect2, varscan2
- ALDH3B1 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV50288657; called by muse, mutect2
- AP1G1 | c.1880A>C p.D627A | Missense Mutation (SNP) | VAF 67/101 reads (66%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55489110, COSV55492909; called by muse, mutect2, varscan2
- ARAP3 | c.3985C>G p.Q1329E | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.087); catalogued as COSV53350647; called by muse, mutect2, varscan2
- ARHGEF10L | c.37G>T p.G13* | Nonsense Mutation (SNP) | VAF 32/92 reads (35%) | catalogued as COSV63419729; called by muse, mutect2
- BRI3BP | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58296113, COSV58296921; called by muse, mutect2, varscan2
- CEP104 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 95/134 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV65517331; called by muse, mutect2, varscan2
- COL22A1 | c.2639G>A p.G880E | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57336330; called by muse, mutect2, varscan2
- CUL3 | c.177A>C p.R59S | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52364677; called by muse, mutect2, varscan2
- CYP27B1 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV56985263; called by muse, mutect2, varscan2
- DMXL1 | c.661A>T p.I221F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV60711218; called by muse, mutect2, varscan2
- DNAH10 | c.5992G>A p.G1998S (on ENST00000409039; = p.G1937S on NM_207437.3) | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762655728, COSV68993618; called by muse, mutect2, varscan2
- DNAH3 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 106/383 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs1415191399, COSV54521057; called by muse, mutect2, varscan2
- EXPH5 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777762788, COSV56202175; called by muse, mutect2, varscan2
- FAM168B | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 147/229 reads (64%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); catalogued as COSV66304061; called by muse, mutect2, varscan2
- FAM221A | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61387804, COSV61388674; called by muse, mutect2, varscan2
- FOXD2 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs1255061130, COSV58304031; called by muse, mutect2, varscan2
- GTF3C1 | c.6100G>A p.V2034M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs143019604; called by muse, mutect2, varscan2
- KCNH5 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1274890582, COSV59760000; called by muse, mutect2, varscan2
- KCNT1 | c.652C>G p.P218A (on ENST00000488444; = p.P237A on NM_020822.3) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53701306; called by muse, mutect2, varscan2
- KIAA1755 | c.1224G>T p.E408D | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV54076437; called by muse, mutect2, varscan2
- KRT86 | c.1187A>G p.K396R | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs542735645, COSV53292631; called by muse, mutect2, varscan2
- MEOX2 | c.161C>G p.P54R | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV56289860; called by muse, mutect2, varscan2
- MUC17 | c.2111A>G p.E704G | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as COSV60288307; called by muse, mutect2, varscan2
- MUC2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated, low confidence (0.1); catalogued as rs375767205; called by muse, mutect2, varscan2
- PAK5 | c.1810G>T p.V604F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62027148, COSV62031211; called by muse, mutect2, varscan2
- PIK3C2G | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.085); catalogued as COSV56808801; called by muse, mutect2, varscan2
- PKP2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs796827562, COSV50730648; called by muse, mutect2
- POLD1 | c.2396T>A p.F799Y | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV54530581; called by muse, mutect2, varscan2
- PRAMEF12 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 47/120 reads (39%) | catalogued as rs201386508; called by muse, mutect2, varscan2
- PRDX6 | c.316A>G p.R106G | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61165484; called by muse, mutect2, varscan2
- PRR32 | c.793T>A p.F265I | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV64420526; called by muse, mutect2, varscan2
- RAPH1 | c.3115G>C p.G1039R | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as COSV55583843; called by muse, mutect2, varscan2
- RYR1 | c.10954A>T p.M3652L | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769081932, COSV62097031; called by muse, mutect2, varscan2
- SAMD9L | c.1237T>A p.Y413N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59081470; called by muse, mutect2, varscan2
- SGK2 | c.592T>C p.F198L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58312948; called by muse, mutect2, varscan2
- SIPA1L2 | c.2799G>C p.R933S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV53390269; called by muse, mutect2, varscan2
- SLC35F5 | c.1052T>G p.V351G | Missense Mutation (SNP) | VAF 78/119 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55518419; called by muse, varscan2
- SNTG2 | c.823A>T p.N275Y | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV57982416; called by muse, mutect2, varscan2
- SREBF2 | c.2251C>A p.H751N | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV63331199, COSV63331867; called by muse, mutect2, varscan2
- SRGAP1 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV61894278, COSV61897892; called by muse, mutect2, varscan2
- SSH2 | c.3985A>G p.T1329A | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as rs764671277, COSV52172123; called by muse, mutect2, varscan2
- TANGO6 | c.1736G>T p.G579V | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV55765276; called by muse, mutect2, varscan2
- TOP1MT | c.1524C>G p.H508Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.131); catalogued as COSV61317700; called by muse, mutect2, varscan2
- TSHZ3 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778179502, COSV53671290; called by muse, mutect2, varscan2
- VPS50 | c.1952A>T p.Y651F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV58507467; called by muse, mutect2, varscan2
- WDR81 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs1277389092, COSV58482672; called by muse, mutect2, varscan2
- YJEFN3 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV53063644; called by muse, mutect2, varscan2
- ZNF548 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 115/298 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253755849, COSV60240969; called by muse, mutect2, varscan2
- ZNF770 | c.16A>T p.N6Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV62544296; called by muse, mutect2, varscan2
- CIART | c.474_491del p.M158_R163del | In Frame Del (DEL) | VAF 50/186 reads (27%) | called by mutect2, pindel, varscan2
- COL21A1 | c.2389dup p.C797Lfs*19 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- KIF1A | c.4830del p.Y1611Mfs*185 (on ENST00000320389 / NM_001379639.1; = p.Y1603Mfs*185 on NM_004321.8 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 146/247 reads (59%) | called by mutect2, varscan2
- PCDH12 | c.2549dup p.N851Qfs*47 | Frame Shift Ins (INS) | VAF 78/136 reads (57%) | called by mutect2, varscan2
- PRUNE1 | c.921del p.L308Sfs*17 | Frame Shift Del (DEL) | VAF 35/113 reads (31%) | called by mutect2, pindel, varscan2
- RIN3 | c.558dup p.P187Sfs*30 | Frame Shift Ins (INS) | VAF 21/43 reads (49%) | called by mutect2, pindel, varscan2
- RTL1 | c.988_995delinsT p.L330Wfs*16 | Frame Shift Del (DEL) | VAF 26/58 reads (45%) | called by pindel, varscan2*
- SAMD14 | c.928_929del p.Q310Vfs*4 (on ENST00000330175 / NM_001257359.2; = p.Q338Vfs*4 on NM_174920.4) | Frame Shift Del (DEL) | VAF 50/213 reads (23%) | called by mutect2, pindel, varscan2
- ZNF800 | c.180_185del p.L61_L62del | In Frame Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel
- ARHGAP11A | c.2493T>C p.L831= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV55706274; called by muse, mutect2, varscan2
- HDAC9 | c.2880C>T p.A960= | Silent (SNP) | VAF 45/186 reads (24%) | catalogued as rs534633020, COSV67773006; called by muse, mutect2, varscan2
- IL1A | c.72C>A p.S24= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV54519547; called by muse, mutect2, varscan2
- KIT | c.903C>G p.V301= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as COSV55399989; called by muse, mutect2, varscan2
- LAMA2 | c.6423C>T p.A2141= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV70346917; called by muse, mutect2, varscan2
- LRRC43 | c.331T>C p.L111= | Silent (SNP) | VAF 85/196 reads (43%) | catalogued as rs373684289; called by muse, mutect2, varscan2
- NEUROD6 | c.948C>T p.Y316= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as rs773060233, COSV51769977; called by muse, mutect2, varscan2
- NSRP1 | c.1518G>T p.G506= | Silent (SNP) | VAF 89/159 reads (56%) | catalogued as COSV55933899; called by muse, mutect2, varscan2
- PAK5 | c.1809G>A p.L603= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV62027161; called by muse, mutect2, varscan2
- PNLIPRP1 | c.582T>C p.D194= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV62611796; called by muse, mutect2, varscan2
- PPP1R36 | c.702G>A p.K234= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV53901961; called by muse, mutect2, varscan2
- REPS1 | c.1746C>A p.A582= (on ENST00000450536 / NM_001286611.2; = p.A581= on NM_031922.4) | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV57810665; called by muse, mutect2, varscan2
- SNTG2 | c.822C>A p.A274= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as COSV57982396; called by muse, mutect2, varscan2
- TBC1D4 | c.1299G>T p.L433= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV66489175; called by muse, mutect2, varscan2
- TEP1 | c.5637C>G p.A1879= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV52992395; called by muse, mutect2, varscan2
- ZFAND2B | c.388C>T p.L130= | Silent (SNP) | VAF 102/146 reads (70%) | catalogued as rs1161906484, COSV54695826; called by muse, mutect2, varscan2
- CNTRL | c.3963+23C>T | Intron (SNP) | VAF 38/101 reads (38%) | called by muse, mutect2, varscan2
- JRKL | c.*1121T>G | 3'UTR (SNP) | VAF 24/35 reads (69%) | called by muse, mutect2, varscan2
- PIGC | c.-208-88T>A | Intron (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- TPM4 | c.*190del | 3'UTR (DEL) | VAF 26/85 reads (31%) | catalogued as COSV99959456; called by mutect2, pindel, varscan2
- ZNF276 | c.510-16C>T | Intron (SNP) | VAF 64/209 reads (31%) | catalogued as rs1196843838; called by muse, varscan2
- ZNF451 | c.186+2651C>T | Intron (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- ZNF805 | c.*55T>A | 3'UTR (SNP) | VAF 22/63 reads (35%) | catalogued as COSV100846060; called by muse, mutect2, varscan2
